Somatic mutation profile of tumor specimen TCGA-4H-AAAK-01A (aliquot TCGA-4H-AAAK-01A-12D-A41F-09) from TCGA case TCGA-4H-AAAK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.3 years (18,371 days).
Specimen TCGA-4H-AAAK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79d806ca-c990-4d8b-b94a-d609a6b73277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4H-AAAK-10A (Blood Derived Normal), aliquot TCGA-4H-AAAK-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/613b326e-f18c-4474-b169-f10273c1b065

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP5Z1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196396832, COSV100804200; called by muse, mutect2
- CDH1 | c.1711+1G>T p.X571_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV55742121, COSV55743721, COSV99028507, COSV99932472; called by muse, mutect2, varscan2
- ECSIT | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99369188; called by muse, mutect2, varscan2
- ERF | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99724793; called by muse, mutect2, varscan2
- FBN3 | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99561541; called by muse, mutect2, varscan2
- HERC5 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99988039; called by muse, mutect2, varscan2
- HUWE1 | c.9521G>A p.R3174H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53333498; called by muse, mutect2, varscan2
- MELTF | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778156728, COSV56381953; called by muse, mutect2, varscan2
- NPHP4 | c.2693G>A p.G898D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV100977095; called by muse, mutect2, varscan2
- PCDH12 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs767375233, COSV99188016; called by muse, mutect2
- RUNX1T1 | c.743C>A p.T248N (on ENST00000265814 / NM_001198628.1; = p.T221N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV99753982; called by muse, mutect2, varscan2
- SLC43A2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100025152; called by muse, mutect2, varscan2
- SYT2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1255861877, COSV100937183; called by muse, varscan2
- ZNF648 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100374713; called by muse, mutect2
- RBP3 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2
- ELAPOR1 | c.85C>T p.L29= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- LRATD2 | c.201G>T p.P67= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100513642; called by muse, mutect2, varscan2
- PCDHB2 | c.1716G>A p.A572= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99166129; called by muse, mutect2, varscan2
- TPSAB1 | c.774C>G p.T258= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100127157; called by muse, mutect2, varscan2
- RCL1 | c.971+781G>A | Intron (SNP) | VAF 7/35 reads (20%) | catalogued as rs533430622, COSV100762139; called by muse, mutect2, varscan2
